Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A413, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A413-01A (Primary Tumor).

Procurement Date: Laterality: Tumor consists of papillae having an fine fibrovascular stalk or folliculae covered by a single to mutiple layers of cuboidal epithelial cells. Tumor invades in capsule or vessle or begnin tissue. The cells tend to maintain their polarity. Nulei are quite regular and contain finely dispersed chromatin, or intranuclear grooves. There are some psammoma bodies. Tumor is hemorrhage, fibrous and invasion of lymphocytes.

Path Report: Tumor type: Papillary carcinoma

Tumor size: 1.5cm in diameter

Laterality: left

Focality: unifocal

Extrathyroidal extension: no

ICD-O-3

carcinoma, papillary, thyroid

8260/3

site: thyroid, NOS

C73.9

7-20-12 rp

Source: NCI Genomic Data Commons file 143c56f1-e630-42fa-9e1e-9a1a98b9316f (TCGA-E8-A413.67AA3628-75B9-4045-869C-CE3A28B2DA1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).